Gene-level copy-number profile of tumor specimen TCGA-IB-A5SP-01A from TCGA case TCGA-IB-A5SP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.5 years (28,317 days).
Specimen TCGA-IB-A5SP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.5d617dc0-94be-4480-a1c4-29c2ab609464.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-A5SP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b6cd54e3-99bf-4e55-99e1-be34c7e2d2ba

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 163; copy number 2: 14,269; copy number 3: 15,470; copy number 4: 29,363; copy number 5: 526; copy number 6: 10; copy number 7: 2; copy number 8: 2; copy number 9: 1; copy number 11: 1; copy number 12: 2; copy number 13: 2; copy number 19: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-A5SP-01A-11D-A32M-01): tumor purity 0.77, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:89,900,664–89,990,883, 1 gene, copy number 19 (within-gene range 4–19): AC113167.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 9: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 13: AC139365.2, AC139365.1.
- chr8:105,737,280–105,737,765, 1 gene, copy number 12: RPL12P24.
- chr8:131,712,512–131,712,980, 1 gene, copy number 11: AC060788.1.
- chr11:21,383,801–21,383,909, 1 gene, copy number 12: RNA5SP337.

Autosomal genes at a single copy (total copy number 1): 163. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
